Surgical pathology report (de-identified scan), TCGA case TCGA-21-1080, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1080-01A (Primary Tumor).

[page 1 of 2]
Clinical History/Diagnosis: Not entered.

Source of Specimen(s):

A: L4 LN

B: R4 LN

C: LEVEL 7 LN

D: CYTO

E: L LEVEL 8 LN

F: LEVEL 7 LN

G: L LEVEL 10 LN

H: L LUNG

Gross Description:

GROSS DESCRIPTION: Received fresh for frozen section evaluation is a 1031 gram, 22.0 x 12.5 x 6.0cm left pneumonectomy. It is covered by a red-purple focally anthracotic stained pleura having a 7.5 x 7.5 x 0.8cm fragment of yellow-tan attached parietal pleura in the superior segment of the lower lobe. There is up to 1.5cm of attached bronchus and the bronchial margin is submitted for frozen section evaluation and the frozen section residue is submitted in one block. On sectioning the lung at the junction of the upper and lower lobes, there is a 9.5 x 7.5 x 6.5cm firm mass. This lies beneath the previously described parietal pleura. The cut surfaces of the mass are tan to gray-tan, variegated, firm and nodular with focal anthracotic stain. The margins are irregular. The remaining cut surfaces of the upper lobe are red-purple, glistening and soft. On sectioning the lower lobe the cut surfaces range from pink-red to golden yellow having focal areas of a yellow-tan exudate. There are several palpable hilar lymph nodes, 1.0 to 2.0cm in greatest dimension. The cut surface of each is tan to gray-black and focally anthracotic stained. A representative section of each lymph node is submitted. Representative sections are submitted in thirteen blocks.

DESIGNATION OF SECTIONS: 8FS - frozen section, bronchial margin, 8A to 8B - vascular margin, 8C thru 8F - tumor with inked pleura, 8G thru 8H - random tumor sections, 8I - random sections upper lobe, 8J thru 8K - random section lower lobe, 8L thru 8M - hilar lymph nodes

SUMMARY OF SECTIONS: 8FS-1, 8A-3, 8B-1, 8C-1, 8D-1, 8E-1, 8F-1, 8G-1, 8H-1, 8I-2, 8J-1, 8K-1, 8L-2, 8M-3.

Final Diagnosis:

DIAGNOSIS:

1. L4 LYMPH NODES:

- TWO NEGATIVE LYMPH NODES (0/2).

[page 2 of 2]
2. R4 LYMPH NODE:

- TWO NEGATIVE LYMPH NODES (0/2).

3. LEVEL 7 LYMPH NODE:

- ONE NEGATIVE LYMPH NODE (0/1).

4. CYTOLOGY.

5. LEFT LEVEL 8 LYMPH NODE:

- ONE NEGATIVE LYMPH NODE (0/1).

6. LEVEL L7 LYMPH NODES:

- FIVE NEGATIVE LYMPH NODES (0/5).

7. LEFT LEVEL 10 LYMPH NODE:

- ONE NEGATIVE LYMPH NODE (0/1).

8. LEFT LUNG:

SYNOPTIC REPORT FOR LUNG CANCER

- A NEOPLASM IS PRESENT

- LOCATION OF TUMOR IS LEFT LUNG

- THE HISTOLOGIC CLASSIFICATION OF THE TUMOR IS SQUAMOUS CELL (EPIDERMOID)

CARCINOMA, KERATINIZING TYPE

- POORLY DIFFERENTIATED

- THE MAXIMUM DIMENSION OF THE TUMOR IS 9.5 CM.

- LYMPHATIC INVASION BY TUMOR IS ABSENT

- VENOUS INVASION BY TUMOR IS ABSENT

- ARTERIAL INVASION BY TUMOR IS ABSENT

- INVASION INTO BUT NOT THROUGH THE PLEURA BY TUMOR IS ABSENT

- INVASION THROUGH THE PLEURA BY TUMOR IS ABSENT

- TUMOR NECROSIS IS MODERATE

- THE SURGICAL MARGINS ARE UNINVOLVED BY TUMOR

- THE NON-NEOPLASTIC LUNG TISSUE SHOWS PNEUMONIA WITH ABSCESS.

- THE TOTAL NUMBER OF NODES EXAMINED IS: 5

- THE TOTAL NUMBER OF POSITIVE NODES IS: 0

STAGING DATA

T2

N-0

Source: NCI Genomic Data Commons file b09f4e3c-fecb-4f14-b5ee-59cbb370778d (TCGA-21-1080.C5E7CFA9-2EE0-455F-80D2-E5ECC721D1EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).